Somatic mutation profile of tumor specimen TCGA-61-1919-01A (aliquot TCGA-61-1919-01A-01W-0699-08) from TCGA case TCGA-61-1919, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 58.0 years (21,199 days).
Specimen TCGA-61-1919-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5855a3ca-325a-4c59-932c-55d450d0b278.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1919-11A (Solid Tissue Normal), aliquot TCGA-61-1919-11A-01W-0700-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e4b6d107-95fd-44de-aa14-c9b6934e9e53

The open-access MAF lists 57 somatic variants for this specimen: 47 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 9, Nonsense Mutation 3, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 64/132 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB7 | c.800T>C p.L267S (on ENST00000373394 / NM_001271696.3; = p.L268S on NM_004299.6) | Missense Mutation (SNP) | VAF 18/129 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV53721468; called by muse, mutect2, varscan2
- AHNAK | c.12758A>G p.K4253R | Missense Mutation (SNP) | VAF 108/589 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV57220318; called by muse, mutect2, varscan2
- AKAP6 | c.6452A>G p.D2151G | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as COSV99801699; called by muse, mutect2
- AP2B1 | c.1507G>A p.V503I | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.028); catalogued as COSV52000971; called by muse, mutect2, varscan2
- APC | c.5646A>T p.R1882S | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV57358726; called by muse, mutect2, varscan2
- CAT | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99573288; called by muse, mutect2
- CDYL2 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs1273588390, COSV73653924; called by muse, mutect2
- CFTR | c.1158C>G p.N386K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.722); catalogued as COSV50069608; called by muse, mutect2
- CRMP1 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV100271999; called by muse, mutect2
- DSG1 | c.4G>C p.D2H | Missense Mutation (SNP) | VAF 42/766 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as COSV99936139, COSV99936462; called by muse, mutect2
- EHD3 | c.627C>A p.N209K | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV59031799; called by muse, mutect2, varscan2
- EPB41L3 | c.2993T>C p.L998P | Missense Mutation (SNP) | VAF 30/489 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.431); catalogued as COSV100549491; called by muse, mutect2
- ERO1A | c.859C>T p.R287* | Nonsense Mutation (SNP) | VAF 62/256 reads (24%) | catalogued as rs774016389, COSV67471612; called by muse, mutect2, varscan2
- EYA3 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 17/338 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100870258; called by muse, mutect2
- GCM2 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 53/916 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.573); catalogued as COSV65276640; called by muse, mutect2
- GPR173 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60236910; called by muse, mutect2, varscan2
- INSIG1 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 14/165 reads (8%) | catalogued as rs1383243939, COSV60921057; called by muse, mutect2
- KCNK18 | c.290G>T p.R97M | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.67); catalogued as COSV57972392; called by muse, mutect2, varscan2
- LAMB1 | c.1051T>C p.Y351H | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55967046; called by muse, mutect2, varscan2
- MAD2L1BP | c.545G>T p.S182I | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.602); catalogued as COSV100937852; called by muse, mutect2
- MROH7 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 13/363 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100273634, COSV59875015; called by muse, mutect2
- MYO5B | c.3988G>A p.G1330S | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT tolerated (0.81); PolyPhen benign (0.102); catalogued as rs557902503, COSV53211266; called by muse, mutect2
- NUP205 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV53661969; called by muse, mutect2, varscan2
- OR11G2 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1224442763, COSV62131736; called by muse, mutect2, varscan2
- PCDHB11 | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.106); catalogued as rs1270825649, COSV61312680; called by muse, mutect2, varscan2
- PKHD1 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 47/263 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs374645464; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLAAT4 | c.401A>C p.K134T | Missense Mutation (SNP) | VAF 91/423 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV99737744; called by muse, mutect2, varscan2
- PRAMEF2 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 11/278 reads (4%) | catalogued as COSV53573666; called by muse, mutect2
- RASGRF2 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs943759264, COSV54130009; called by muse, mutect2
- RFPL2 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.131); catalogued as rs1278625212, COSV50708899; called by muse, mutect2
- SETDB1 | c.2090T>C p.I697T | Missense Mutation (SNP) | VAF 41/343 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.152); catalogued as COSV54987248, COSV99645701; called by muse, mutect2, varscan2
- SLC25A23 | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV51193140; called by muse, mutect2, varscan2
- SLC45A2 | c.839A>G p.N280S | Missense Mutation (SNP) | VAF 47/634 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as COSV99672822; called by muse, mutect2
- SRGN | c.19A>C p.K7Q | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.015); catalogued as COSV99653755; called by muse, mutect2
- STOX2 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1198145483, COSV57853835; called by muse, mutect2, varscan2
- TENT4A | c.1894G>A p.V632I | Missense Mutation (SNP) | VAF 46/309 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.399); catalogued as COSV50096924; called by muse, mutect2, varscan2
- TEP1 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs751992143, COSV52995671; called by muse, mutect2, varscan2
- TERF2 | c.1505C>A p.A502D | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV99651557; called by muse, mutect2
- TRAF6 | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 86/396 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.03); catalogued as COSV61922990; called by muse, mutect2, varscan2
- TRPS1 | c.1003T>A p.C335S (on ENST00000220888 / NM_001330599.2; = p.C348S on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99631685; called by muse, mutect2, varscan2
- TTN | c.34765C>G p.P11589A (on ENST00000591111; = p.P10662A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/163 reads (14%) | PolyPhen benign (0.085); catalogued as COSV60175536, COSV60245794, COSV60274602; called by muse, mutect2, varscan2
- ZC3H4 | c.670C>G p.L224V | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53414565; called by muse, mutect2, varscan2
- ZNF407 | c.3796G>A p.V1266I | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs751450561, COSV55259670; called by muse, mutect2, varscan2
- NBPF9 | c.1456_1459delinsAT p.H486Mfs*4 | Frame Shift Del (DEL) | VAF 163/1676 reads (10%) | called by pindel, varscan2*
- ST3GAL6 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 18/472 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- ZDHHC18 | c.1142C>T p.A381V | Missense Mutation (SNP) | VAF 150/270 reads (56%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.034); called by mutect2, varscan2
- ARSJ | c.1173G>A p.Q391= | Silent (SNP) | VAF 173/708 reads (24%) | catalogued as rs1477460901, COSV59537010; called by muse, mutect2, varscan2
- EPHA1 | c.285C>T p.V95= | Silent (SNP) | VAF 91/197 reads (46%) | catalogued as COSV51972973; called by muse, mutect2, varscan2
- MYCBP2 | c.11479C>A p.R3827= (on ENST00000357337; = p.R3865= on NM_015057.5) | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as COSV100630676, COSV62010851; called by muse, mutect2
- NRAP | c.1923G>A p.K641= (on ENST00000359988 / NM_001322945.2; = p.K606= on NM_006175.4) | Silent (SNP) | VAF 19/233 reads (8%) | catalogued as COSV100748473; called by muse, mutect2
- NRXN2 | c.900C>T p.Y300= | Silent (SNP) | VAF 87/220 reads (40%) | catalogued as rs540195301, COSV55457304; called by muse, mutect2, varscan2
- OR2B11 | c.780T>A p.I260= | Silent (SNP) | VAF 74/404 reads (18%) | catalogued as COSV59510724; called by muse, mutect2, varscan2
- PAX6 | c.759A>G p.R253= | Silent (SNP) | VAF 28/282 reads (10%) | catalogued as COSV53794480; called by muse, mutect2
- TDRKH | c.417C>A p.I139= | Silent (SNP) | VAF 9/225 reads (4%) | catalogued as COSV100917973; called by muse, mutect2
- WSCD2 | c.1578C>T p.L526= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs752849885, COSV54577763; called by muse, mutect2, varscan2
- OR2W5 | n.348C>T | RNA (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
